Somatic mutation profile of tumor specimen TCGA-C5-A1BI-01B (aliquot TCGA-C5-A1BI-01B-11D-A13W-08) from TCGA case TCGA-C5-A1BI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 31.7 years (11,564 days).
Specimen TCGA-C5-A1BI-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d4d37a5-aa5e-4600-b132-588a7a485889.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BI-10A (Blood Derived Normal), aliquot TCGA-C5-A1BI-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b728ee5-b140-43ff-94c4-e1962f8645d7

The open-access MAF lists 135 somatic variants for this specimen: 92 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 37, RNA 3, Intron 2, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5165C>T p.S1722F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs80357104, CM1010524, COSV58794522; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLPB | c.1700A>G p.Y567C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150857620, CM150843; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1183795725, COSV56997874; called by muse, mutect2, varscan2
- ADAMTS16 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs1344462480, COSV56997886; called by muse, mutect2, varscan2
- AEBP1 | c.2256G>C p.E752D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as COSV56259425; called by muse, varscan2
- AFF2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100648832; called by muse, mutect2
- BRWD1 | c.6190G>A p.E2064K | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV60899538; called by muse, mutect2, varscan2
- BTK | c.1909-1G>C p.X637_splice | Splice Site (SNP) | VAF 29/193 reads (15%) | catalogued as COSV58121894; called by muse, mutect2, varscan2
- CASS4 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64386472, COSV64387410; called by muse, mutect2, varscan2
- CCDC158 | c.2491G>C p.E831Q | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101187147; called by muse, mutect2
- CEP162 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV57621863; called by muse, mutect2, varscan2
- CERS5 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV58189125, COSV58189786; called by muse, mutect2, varscan2
- CHL1 | c.2581C>T p.H861Y (on ENST00000397491 / NM_001253387.1; = p.H877Y on NM_006614.4) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.456); catalogued as COSV56598317, COSV99851301; called by muse, mutect2, varscan2
- CLVS2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs376660185, COSV99033987; called by muse, mutect2, varscan2
- CNTNAP4 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as COSV100269359; called by muse, mutect2
- COL4A5 | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV60355920, COSV60366255; called by muse, varscan2
- CTDSPL2 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947213; called by muse, mutect2, varscan2
- CTNNA2 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV63565176, COSV63573771; called by muse, mutect2, varscan2
- CTSV | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV52345267; called by muse, mutect2, varscan2
- CUL1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57387441, COSV57390472; called by muse, mutect2, varscan2
- DDI1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56385497; called by muse, mutect2, varscan2
- DOCK4 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs1214818257, COSV70240161; called by muse, mutect2, varscan2
- DPY19L3 | c.1446-1G>C p.X482_splice | Splice Site (SNP) | VAF 42/321 reads (13%) | catalogued as COSV60478461; called by muse, mutect2, varscan2
- DR1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV64725726; called by muse, varscan2
- E2F5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs1336441586, COSV99809285; called by muse, mutect2
- EDDM3A | c.324G>C p.E108D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as COSV58795349; called by muse, mutect2, varscan2
- F2R | c.299G>C p.W100S | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59929573; called by muse, mutect2, varscan2
- FEM1B | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs777760220, COSV60989049; called by muse, mutect2, varscan2
- FRY | c.7768G>A p.E2590K | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs751570265, COSV66568795, COSV66574139; called by muse, mutect2, varscan2
- GFPT2 | c.1785G>A p.M595I | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV53810432; called by muse, mutect2, varscan2
- H4C12 | c.311G>C p.*104Sext*? | Nonstop Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV62743637, COSV62743749; called by muse, mutect2, varscan2
- IGSF1 | c.2798G>C p.G933A | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as COSV63838711, COSV63841056; called by muse, mutect2, varscan2
- IQSEC3 | c.2896G>A p.E966K (on ENST00000538872 / NM_001170738.2; = p.E663K on NM_015232.1) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58285191; called by muse, mutect2, varscan2
- ITGBL1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV66009713; called by muse, mutect2, varscan2
- KANSL1L | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99910143; called by muse, mutect2
- KIF16B | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61709780; called by muse, mutect2, varscan2
- LAMC1 | c.4759C>T p.R1587C | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs746805266, COSV51154611; called by muse, mutect2, varscan2
- LRRC37A3 | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 49/468 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV59762504, COSV59764408; called by muse, mutect2, varscan2
- MAEL | c.610C>G p.H204D | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV63112551; called by muse, mutect2, varscan2
- MAP4K3 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55715457; called by muse, mutect2, varscan2
- MGA | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV54958399; called by muse, mutect2, varscan2
- MX1 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV55820086, COSV55820160; called by muse, mutect2, varscan2
- MYCBP | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1200695685, COSV66920646; called by muse, mutect2, varscan2
- MYH7 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV62521402; called by muse, mutect2, varscan2
- MYO15A | c.5773C>G p.L1925V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV52760786, COSV52763461; called by muse, mutect2, varscan2
- NEB | c.5807G>A p.G1936E | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767095639, COSV51435936; called by muse, varscan2
- NLGN4X | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1323836608, COSV52027286; called by muse, mutect2, varscan2
- NTNG1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as rs780180788, COSV53979231; called by muse, mutect2, varscan2
- NXF1 | c.1768C>G p.Q590E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV99585739; called by muse, mutect2
- OR3A1 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.033); catalogued as COSV60163471; called by muse, mutect2, varscan2
- PI4KA | c.2473G>C p.E825Q | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.235); catalogued as COSV55416554; called by muse, mutect2, varscan2
- PIWIL4 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV54410784; called by muse, mutect2, varscan2
- PPEF1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777810268, COSV62996206; called by muse, mutect2, varscan2
- PRICKLE3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.522); catalogued as rs144390456, COSV66235124; called by muse, mutect2, varscan2
- PRRG1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.021); catalogued as COSV66158164; called by muse, mutect2, varscan2
- PUM2 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV57580582; called by muse, mutect2, varscan2
- PWWP2B | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1215289186, COSV100535616; called by muse, mutect2, varscan2
- RCHY1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61008888; called by muse, mutect2, varscan2
- RECQL5 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV58643300; called by muse, mutect2, varscan2
- ROBO3 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV67301704; called by muse, mutect2, varscan2
- RTL10 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.112); catalogued as COSV60736012; called by muse, mutect2, varscan2
- RYR2 | c.10811G>A p.R3604Q | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs56228594, COSV63692889, COSV63714903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBF2 | c.5341G>A p.E1781K | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV56296180, COSV99813073; called by muse, mutect2
- SETX | c.4850C>T p.S1617F | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs572037695, COSV56381690; called by muse, mutect2, varscan2
- SHBG | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as rs1183229885, COSV52647341; called by muse, mutect2
- SHPRH | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51613630; called by muse, mutect2, varscan2
- SLC28A1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54482216; called by muse, mutect2, varscan2
- SMG1 | c.5720C>T p.S1907F | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV67171967; called by muse, mutect2, varscan2
- SMG8 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV56284401, COSV56286215; called by muse, mutect2, varscan2
- SPTAN1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV100824037, COSV63988440; called by muse, mutect2, varscan2
- ST6GAL2 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 24/170 reads (14%) | PolyPhen possibly damaging (0.879); catalogued as COSV64525934, COSV64529952; called by muse, mutect2, varscan2
- ST6GAL2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | PolyPhen probably damaging (0.967); catalogued as COSV64528016; called by muse, mutect2, varscan2
- STAT1 | c.1035G>C p.L345F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV61190052, COSV61190130; called by muse, mutect2, varscan2
- STAT3 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV52885605, COSV52886728; called by muse, mutect2, varscan2
- STK31 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1407095656, COSV63458866; called by muse, mutect2
- TARS2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs780461008, COSV64696186; called by muse, mutect2, varscan2
- TIAM1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.254); catalogued as COSV54562100; called by muse, mutect2, varscan2
- TMEM30A | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV57875904; called by muse, mutect2, varscan2
- TOR1A | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV52213975; called by muse, mutect2, varscan2
- UGT1A4 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV59393382; called by muse, mutect2, varscan2
- USP8 | c.2159C>A p.P720Q | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56162195, COSV56162692, COSV56165591; called by muse, mutect2, varscan2
- VPS13A | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 28/251 reads (11%) | catalogued as COSV62433400; called by muse, mutect2, varscan2
- ZC3H12B | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV59049994; called by muse, mutect2, varscan2
- ZFP64 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1489592282, COSV53797164; called by muse, mutect2, varscan2
- ZNF143 | c.1461del p.T488Qfs*2 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | catalogued as COSV100217931; called by mutect2, pindel, varscan2
- ZNF445 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV68539245; called by muse, mutect2, varscan2
- ZNF573 | c.1459C>G p.Q487E (on ENST00000536220 / NM_001172692.1; = p.Q429E on NM_152360.3) | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.431); catalogued as COSV59826856; called by muse, mutect2, varscan2
- ZNF668 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56216655; called by muse, mutect2, varscan2
- ZNF92 | c.1628A>G p.D543G (on ENST00000328747 / NM_152626.4; = p.D474G on NM_007139.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs980858259, COSV60873983; called by muse, mutect2, varscan2
- MDGA1 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.093); called by muse, mutect2
- SUPT20HL2 | c.1757A>T p.Q586L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- ABCG8 | c.921C>T p.I307= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs780422381, COSV55394886; called by muse, mutect2, varscan2
- ADGRE1 | c.615C>T p.S205= | Silent (SNP) | VAF 53/373 reads (14%) | catalogued as COSV51678296; called by muse, mutect2, varscan2
- AKAP13 | c.4329C>G p.L1443= | Silent (SNP) | VAF 42/270 reads (16%) | catalogued as COSV63464411; called by muse, mutect2, varscan2
- ARHGAP33 | c.531C>T p.L177= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV50134662; called by muse, mutect2, varscan2
- AXL | c.2019G>C p.L673= (on ENST00000301178 / NM_021913.5; = p.L664= on NM_001699.6) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV56571432; called by muse, mutect2, varscan2
- BACE1 | c.822G>C p.L274= | Silent (SNP) | VAF 68/549 reads (12%) | catalogued as COSV100474842; called by muse, varscan2
- CAAP1 | c.84C>A p.I28= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs759683083, COSV61700507, COSV61700686; called by muse, mutect2
- CHD4 | c.543C>T p.F181= | Silent (SNP) | VAF 73/550 reads (13%) | catalogued as rs1472488937, COSV58905476; called by muse, mutect2, varscan2
- GPRIN3 | c.1863G>A p.K621= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs1225343577, COSV60885582; called by muse, mutect2, varscan2
- HCN4 | c.2595C>T p.F865= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs904535432, COSV56085395; called by muse, varscan2
- HPSE2 | c.1212G>A p.L404= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs763727430, COSV100984935; called by muse, mutect2
- IQCN | c.129C>G p.L43= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as COSV101148347; called by muse, mutect2
- ITGA10 | c.1131C>T p.F377= | Silent (SNP) | VAF 43/225 reads (19%) | catalogued as COSV65198215; called by muse, mutect2, varscan2
- LVRN | c.399C>T p.I133= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs571373626, COSV63497758; called by mutect2, varscan2
- MC1R | c.189C>T p.I63= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs373344683; ClinVar: likely benign; called by muse, mutect2, varscan2
- MICAL2 | c.4908C>T p.L1636= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as rs945413094, COSV56287406; called by muse, mutect2, varscan2
- NANOG | c.252C>T p.V84= | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as rs759658381, COSV57552036; called by muse, mutect2, varscan2
- NAT9 | c.623G>A p.*208= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV52854074; called by muse, mutect2, varscan2
- NDUFA6 | c.244C>T p.L82= | Silent (SNP) | VAF 42/349 reads (12%) | catalogued as COSV58938924; called by muse, mutect2, varscan2
- NUP98 | c.4170C>T p.F1390= (on ENST00000359171 / NM_001365126.1; = p.F1373= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 45/262 reads (17%) | catalogued as COSV100261479; called by muse, mutect2, varscan2
- PAM | c.468G>A p.E156= | Silent (SNP) | VAF 46/265 reads (17%) | catalogued as COSV57216132; called by muse, mutect2, varscan2
- PCDHB6 | c.2292C>T p.F764= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as COSV50690426; called by muse, mutect2, varscan2
- PJA1 | c.72G>A p.R24= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs1396819044, COSV64053459; called by muse, mutect2, varscan2
- RHPN2 | c.555C>T p.F185= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV54274512; called by muse, mutect2, varscan2
- SEL1L2 | c.324C>T p.D108= | Silent (SNP) | VAF 24/197 reads (12%) | catalogued as COSV53154773; called by muse, mutect2, varscan2
- SETD9 | c.670C>T p.L224= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs539773583, COSV53650768; called by muse, mutect2, varscan2
- SIK2 | c.660G>A p.P220= | Silent (SNP) | VAF 31/255 reads (12%) | catalogued as rs907576423, COSV59254313; called by muse, mutect2, varscan2
- SYNE1 | c.24633C>T p.I8211= (on ENST00000367255 / NM_182961.4; = p.I8140= on NM_033071.3) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs201078523, COSV55056923; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- SYT7 | c.321C>T p.L107= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs917455728, COSV55654193; called by muse, mutect2, varscan2
- TAGAP | c.1620G>A p.P540= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs200549687, COSV57852138; called by muse, mutect2, varscan2
- TAOK3 | c.1593G>A p.K531= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as COSV66826871; called by muse, mutect2, varscan2
- TGFBR3 | c.1458C>T p.T486= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV53028459; called by muse, mutect2, varscan2
- TRMT5 | c.282C>T p.V94= | Silent (SNP) | VAF 49/379 reads (13%) | catalogued as COSV50783926; called by muse, mutect2, varscan2
- TUBA3E | c.147C>T p.F49= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV57270723; called by muse, mutect2, varscan2
- UNC79 | c.4821G>T p.L1607= (on ENST00000393151 / NM_001346218.2; = p.L1430= on NM_020818.5) | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as COSV56398297, COSV56416782, COSV99829658; called by muse, mutect2
- ZBTB12 | c.333G>A p.Q111= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV64994004; called by muse, mutect2, varscan2
- ZNF671 | c.294C>T p.V98= | Silent (SNP) | VAF 42/256 reads (16%) | catalogued as rs1568467808, COSV58053654; called by muse, mutect2, varscan2
- MIR516A1 | n.4C>T | RNA (SNP) | VAF 44/300 reads (15%) | catalogued as rs1227846182; called by muse, mutect2, varscan2
- TTN | c.10360+4966C>G | Intron (SNP) | VAF 13/80 reads (16%) | catalogued as COSV60190064; called by muse, mutect2, varscan2
- TTN | c.10360+3663G>A | Intron (SNP) | VAF 13/92 reads (14%) | catalogued as COSV60190067; called by muse, mutect2, varscan2
- UCHL5 | chr1:193059898 G>A | 5'Flank (SNP) | VAF 3/22 reads (14%) | catalogued as rs1289082927, COSV100814553; called by muse, mutect2
- WASF4P | n.1460C>G | RNA (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- ZNF271P | n.1955C>G | RNA (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
